Somatic mutation profile of tumor specimen MMRF_1991_1_BM_CD138pos (aliquot MMRF_1991_1_BM_CD138pos_T1_KHS5U_L08075) from MMRF case MMRF_1991, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.7 years (21,441 days).
Specimen MMRF_1991_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a3edd43-70fe-4ece-a0d2-b3fa7810a248.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1991_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1991_1_PB_Whole_C2_KHS5U_L08076; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cdf89eca-346e-405e-94b7-4392c163c5b1

The open-access MAF lists 145 somatic variants for this specimen: 65 protein-altering or splice-affecting, 21 silent, 59 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, 3'UTR 35, Silent 21, Intron 14, 5'UTR 5, Nonsense Mutation 4, 3'Flank 3, Frame Shift Del 2, 5'Flank 2, Splice Region 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- TP53 | c.376T>C p.Y126H | Missense Mutation (SNP) | VAF 16/176 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM118879, COSV52661802, COSV52809424, COSV53031989, COSV53515469; called by muse, mutect2
- ACTR2 | c.128C>G p.S43* | Nonsense Mutation (SNP) | VAF 31/45 reads (69%) | catalogued as COSV99573904; called by muse, mutect2, varscan2
- ANKRD11 | c.6752T>C p.L2251P | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs1015762202; called by muse, mutect2, varscan2
- CDC40 | c.572G>T p.G191V | Missense Mutation (SNP) | VAF 53/160 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as COSV104410405; called by muse, mutect2, varscan2
- CDCA7 | c.208C>T p.L70F (on ENST00000347703 / NM_145810.3; = p.L149F on NM_031942.5) | Missense Mutation (SNP) | VAF 45/76 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1456932401; called by muse, mutect2, varscan2
- CHD5 | c.2407C>T p.R803W | Missense Mutation (SNP) | VAF 157/388 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as rs781580398, COSV52425933; called by muse, mutect2, varscan2
- CNBD2 | c.1702C>T p.R568W (on ENST00000373973 / NM_001365709.1; = p.R564W on NM_080834.4) | Missense Mutation (SNP) | VAF 91/186 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs373220798; called by muse, mutect2, varscan2
- EIF4B | c.1778A>G p.Y593C | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.063); catalogued as rs767780708, COSV50402224; called by muse, mutect2, varscan2
- EMG1 | c.17A>G p.D6G | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs782711576; called by muse, mutect2, varscan2
- FUT7 | c.509G>A p.S170N | Missense Mutation (SNP) | VAF 49/74 reads (66%) | SIFT tolerated (0.24); PolyPhen benign (0.082); catalogued as rs759228767; called by muse, mutect2, varscan2
- HEATR9 | c.242C>T p.T81M | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as rs541044178; called by muse, mutect2, varscan2
- HOMER1 | c.394G>A p.A132T | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs757029273; called by muse, mutect2, varscan2
- IGHV1-3 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT tolerated (0.19); PolyPhen benign (0.075); catalogued as rs782769944; called by muse, varscan2
- IGLV3-1 | c.49T>C p.S17P | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.166); catalogued as rs572483152; called by muse, varscan2
- IGLV3-1 | c.61T>G p.Y21D | Missense Mutation (SNP) | VAF 50/86 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.195); catalogued as rs372924773; called by muse, varscan2
- IGLV3-1 | c.161A>C p.Y54S | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as rs375251465; called by muse, varscan2
- IGLV3-1 | c.311A>C p.Y104S | Missense Mutation (SNP) | VAF 57/105 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs142180628; called by muse, varscan2
- IGLV3-1 | c.314A>G p.Y105C | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs185803370; called by muse, varscan2
- KCNE1 | c.181A>G p.I61V | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.125); catalogued as rs143661740; called by muse, mutect2, varscan2
- MXRA5 | c.1816G>A p.E606K | Missense Mutation (SNP) | VAF 28/30 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs763581529, COSV54241331; called by muse, mutect2, varscan2
- MYH13 | c.2436G>T p.R812S | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV52823398; called by muse, mutect2
- PIEZO2 | c.7704G>C p.M2568I | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV99555280; called by muse, mutect2, varscan2
- PTPRB | c.5684C>T p.P1895L | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs199673074, COSV54240296, COSV99716055; called by muse, mutect2
- RFX1 | c.227C>A p.T76K | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.077); catalogued as COSV54328913; called by muse, mutect2, varscan2
- RPS6KA1 | c.807G>C p.E269D | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs1237554716; called by muse, mutect2, varscan2
- SLCO4A1 | c.1811+6C>G | Splice Region (SNP) | VAF 68/132 reads (52%) | catalogued as rs770713005; called by muse, mutect2, varscan2
- SPAG4 | c.216G>A p.W72* | Nonsense Mutation (SNP) | VAF 12/91 reads (13%) | catalogued as rs1221139354; called by muse, mutect2, varscan2
- ST8SIA5 | c.1025A>G p.K342R | Missense Mutation (SNP) | VAF 66/187 reads (35%) | PolyPhen probably damaging (0.992); catalogued as COSV100164963, COSV59329907; called by muse, mutect2, varscan2
- TCF7L2 | c.1251G>T p.W417C (on ENST00000355995 / NM_001367943.1; = p.W394C on NM_030756.5) | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53336087; called by muse, mutect2, varscan2
- TCP1 | c.1086C>G p.I362M | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.378); catalogued as rs747455768; called by muse, mutect2, varscan2
- TGDS | c.866T>A p.V289D | Missense Mutation (SNP) | VAF 11/11 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as COSV54300611; called by muse, mutect2, varscan2
- ARID2 | c.3827C>T p.T1276I | Missense Mutation (SNP) | VAF 82/180 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- BCR | c.743A>G p.D248G | Missense Mutation (SNP) | VAF 74/169 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.475); called by muse, varscan2
- BRD2 | c.2353T>C p.S785P | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CLASP1 | c.2036C>T p.P679L | Missense Mutation (SNP) | VAF 98/206 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CLDN18 | c.602C>A p.P201Q | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- EGFR | c.1121T>G p.V374G | Missense Mutation (SNP) | VAF 59/184 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- ERO1B | c.455T>C p.I152T | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT tolerated (0.53); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- FOXB1 | c.680C>A p.S227* | Nonsense Mutation (SNP) | VAF 38/65 reads (58%) | called by muse, mutect2, varscan2
- H3C1 | c.134G>C p.G45A | Missense Mutation (SNP) | VAF 68/218 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- IGFLR1 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- KATNAL2 | c.1613_1616del p.V538Efs*52 (on ENST00000356157 / NM_001353899.1; = p.V466Efs*52 on NM_031303.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 28/112 reads (25%) | called by pindel, varscan2
- KCNE1B | c.190A>G p.I64V | Missense Mutation (SNP) | VAF 63/139 reads (45%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LAMA1 | c.291C>A p.S97R | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP3K8 | c.319G>T p.G107* | Nonsense Mutation (SNP) | VAF 83/196 reads (42%) | called by muse, mutect2, varscan2
- MAP3K8 | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 83/198 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MEGF10 | c.3382A>T p.S1128C | Missense Mutation (SNP) | VAF 60/184 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.049); called by muse, varscan2
- NUP133 | c.3262G>A p.G1088S | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.949); called by mutect2, varscan2
- PBRM1 | c.1436T>G p.V479G | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- PCLO | c.8327T>G p.I2776R | Missense Mutation (SNP) | VAF 59/181 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- PSD | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBFA | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 55/209 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- RYK | c.1055del p.L352* (on ENST00000620660 / NM_001005861.2; = p.L349* on NM_002958.4) | Frame Shift Del (DEL) | VAF 50/112 reads (45%) | called by pindel, varscan2
- SLC50A1 | c.121_126dup p.N41_V42dup | In Frame Ins (INS) | VAF 40/106 reads (38%) | called by mutect2, varscan2
- SUGP2 | c.18T>G p.I6M | Missense Mutation (SNP) | VAF 57/190 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SYT12 | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- TRIM42 | c.149G>A p.C50Y | Missense Mutation (SNP) | VAF 61/183 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TYMP | c.903C>G p.D301E | Missense Mutation (SNP) | VAF 49/89 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WFS1 | c.2144G>C p.S715T | Missense Mutation (SNP) | VAF 80/250 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- WNK1 | c.1759A>G p.S587G | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- WWC2 | c.1966A>C p.T656P | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- XRCC6 | c.336T>G p.G112= | Splice Region (SNP) | VAF 37/108 reads (34%) | called by muse, mutect2, varscan2
- ZFP28 | c.2112G>T p.M704I | Missense Mutation (SNP) | VAF 71/195 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF555 | c.1135T>A p.Y379N | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- AJAP1 | c.861C>T p.T287= | Silent (SNP) | VAF 49/119 reads (41%) | catalogued as rs370080285; called by muse, mutect2, varscan2
- BCR | c.648G>A p.Q216= | Silent (SNP) | VAF 72/146 reads (49%) | catalogued as rs1403367655, COSV59936404; called by muse, varscan2
- CRNN | c.1365G>A p.L455= | Silent (SNP) | VAF 144/280 reads (51%) | called by muse, mutect2, varscan2
- CSMD1 | c.3813A>G p.L1271= (on ENST00000520002; = p.L1270= on NM_033225.6) | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs756872608; called by muse, mutect2, varscan2
- DGKD | c.2130C>T p.D710= (on ENST00000264057 / NM_152879.3; = p.D666= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 50/107 reads (47%) | catalogued as rs747461841, COSV51081587; called by muse, mutect2, varscan2
- DGKI | c.1368G>T p.V456= | Silent (SNP) | VAF 73/253 reads (29%) | called by muse, mutect2, varscan2
- IGKV2D-29 | c.303C>T p.S101= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV101534350; called by muse, varscan2
- IGLV3-1 | c.51C>G p.S17= | Silent (SNP) | VAF 34/86 reads (40%) | catalogued as rs376572967; called by muse, varscan2
- JMJD1C | c.6208C>T p.L2070= | Silent (SNP) | VAF 60/134 reads (45%) | catalogued as COSV59513634; called by muse, mutect2, varscan2
- MED13L | c.4152T>A p.T1384= | Silent (SNP) | VAF 21/42 reads (50%) | called by muse, mutect2
- MIA2 | c.807A>G p.E269= | Silent (SNP) | VAF 41/86 reads (48%) | catalogued as rs200245491; called by muse, mutect2, varscan2
- NELL2 | c.2007C>T p.F669= | Silent (SNP) | VAF 34/79 reads (43%) | catalogued as rs772079522, COSV61569372; called by muse, mutect2, varscan2
- RYK | c.1098C>T p.V366= (on ENST00000620660 / NM_001005861.2; = p.V363= on NM_002958.4) | Silent (SNP) | VAF 114/168 reads (68%) | called by muse, varscan2
- SHROOM2 | c.1995C>T p.A665= | Silent (SNP) | VAF 46/46 reads (100%) | catalogued as rs1169940452; called by muse, mutect2, varscan2
- SLC3A2 | c.429G>C p.L143= | Silent (SNP) | VAF 30/63 reads (48%) | called by muse, mutect2, varscan2
- TLK1 | c.2148A>T p.A716= | Silent (SNP) | VAF 34/77 reads (44%) | called by mutect2, varscan2
- UBA2 | c.1560T>C p.D520= | Silent (SNP) | VAF 44/129 reads (34%) | called by muse, mutect2, varscan2
- UBC | c.801C>T p.D267= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as rs774538481, COSV60058390; called by muse, varscan2
- UTP14C | c.393A>G p.V131= | Silent (SNP) | VAF 12/154 reads (8%) | catalogued as rs752827145; called by muse, mutect2
- ZBTB5 | c.102C>T p.H34= | Silent (SNP) | VAF 81/258 reads (31%) | catalogued as rs781724454; called by muse, mutect2, varscan2
- ZFYVE9 | c.1461T>C p.G487= | Silent (SNP) | VAF 53/122 reads (43%) | called by muse, mutect2, varscan2
- ANTXR1 | c.*3757C>T | 3'UTR (SNP) | VAF 30/69 reads (43%) | called by muse, mutect2, varscan2
- ARHGAP26 | c.*3076C>T | 3'UTR (SNP) | VAF 26/70 reads (37%) | called by muse, mutect2, varscan2
- ARHGAP31 | c.*984T>A | 3'UTR (SNP) | VAF 18/52 reads (35%) | called by mutect2, varscan2
- BMP8A | c.673+4004G>A | Intron (SNP) | VAF 16/35 reads (46%) | called by mutect2, varscan2
- C11orf87 | c.*4361G>T | 3'UTR (SNP) | VAF 28/56 reads (50%) | called by muse, mutect2, varscan2
- C16orf46 | c.*89del | 3'UTR (DEL) | VAF 17/39 reads (44%) | called by mutect2, pindel, varscan2
- C4BPB | c.410-1312G>A | Intron (SNP) | VAF 50/79 reads (63%) | called by muse, mutect2, varscan2
- CACNG6 | c.-237C>A | 5'UTR (SNP) | VAF 21/72 reads (29%) | called by muse, mutect2, varscan2
- CAMTA1 | c.4690-1424C>A | Intron (SNP) | VAF 102/219 reads (47%) | called by muse, mutect2, varscan2
- CLDN18 | c.-43G>A | 5'UTR (SNP) | VAF 27/74 reads (36%) | catalogued as COSV99480591; called by muse, mutect2, varscan2
- DLGAP1 | c.*1784T>C | 3'UTR (SNP) | VAF 23/86 reads (27%) | called by muse, mutect2, varscan2
- DYRK1A | chr21:37513138 C>G | 3'Flank (SNP) | VAF 17/41 reads (41%) | called by muse, mutect2, varscan2
- EEF1E1 | c.87+651A>G | Intron (SNP) | VAF 38/122 reads (31%) | called by muse, mutect2, varscan2
- FA2H | c.*683T>A | 3'UTR (SNP) | VAF 14/45 reads (31%) | called by muse, mutect2, varscan2
- FAM20C | c.1445+99T>A | Intron (SNP) | VAF 27/71 reads (38%) | called by muse, mutect2, varscan2
- FAN1 | c.2489-85T>A | Intron (SNP) | VAF 10/26 reads (38%) | called by muse, varscan2
- GPAM | c.*2912T>C | 3'UTR (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- GTF2F1 | c.*199T>A | 3'UTR (SNP) | VAF 25/70 reads (36%) | called by muse, mutect2, varscan2
- HIP1 | c.*3718C>T | 3'UTR (SNP) | VAF 8/19 reads (42%) | called by muse, mutect2, varscan2
- IMP4 | c.*209T>C | 3'UTR (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2, varscan2
- ITGA1 | c.*3998A>G | 3'UTR (SNP) | VAF 65/96 reads (68%) | catalogued as rs1395556419; called by muse, mutect2, varscan2
- JDP2 | c.*73C>T | 3'UTR (SNP) | VAF 57/119 reads (48%) | catalogued as rs1170192908; called by muse, mutect2, varscan2
- KCNN3 | c.*320G>A | 3'UTR (SNP) | VAF 87/180 reads (48%) | called by muse, mutect2, varscan2
- LINGO1 | c.*842_*844del | 3'UTR (DEL) | VAF 22/90 reads (24%) | called by pindel, varscan2
- MAD1L1 | c.1999-33059G>C | Intron (SNP) | VAF 27/106 reads (25%) | called by muse, mutect2, varscan2
- MC1R | chr16:89915077 C>A | 5'Flank (SNP) | VAF 67/142 reads (47%) | called by muse, mutect2, varscan2
- MGAT4B | c.98-248A>T | Intron (SNP) | VAF 45/130 reads (35%) | called by muse, mutect2, varscan2
- MGMT | c.*284G>A | 3'UTR (SNP) | VAF 6/63 reads (10%) | called by muse, mutect2
- MLX | c.241+154_241+168del | Intron (DEL) | VAF 21/44 reads (48%) | called by mutect2, pindel, varscan2
- MRO | c.*3240_*3252del | 3'UTR (DEL) | VAF 15/83 reads (18%) | called by mutect2, varscan2
- MRPL40 | c.53+52C>T | Intron (SNP) | VAF 28/59 reads (47%) | catalogued as rs1236490052; called by muse, mutect2, varscan2
- MRPL43 | c.*1268G>C | 3'UTR (SNP) | VAF 21/199 reads (11%) | called by muse, mutect2, varscan2
- MUCL1 | c.*68T>A | 3'UTR (SNP) | VAF 134/313 reads (43%) | called by muse, mutect2, varscan2
- NIPAL3 | c.*45T>C | 3'UTR (SNP) | VAF 34/62 reads (55%) | called by muse, mutect2, varscan2
- NR1D2 | c.-137C>G | 5'UTR (SNP) | VAF 12/20 reads (60%) | called by muse, mutect2, varscan2
- PCDH10 | c.*426A>G | 3'UTR (SNP) | VAF 9/50 reads (18%) | called by muse, mutect2, varscan2
- PHF3 | c.*1165T>C | 3'UTR (SNP) | VAF 27/95 reads (28%) | called by muse, mutect2, varscan2
- PNPLA6 | c.3427+131C>T | Intron (SNP) | VAF 12/44 reads (27%) | called by muse, varscan2
- PPFIBP1 | c.270+1878C>T | Intron (SNP) | VAF 21/47 reads (45%) | called by muse, mutect2, varscan2
- PPP1R9A | c.*290G>C | 3'UTR (SNP) | VAF 21/55 reads (38%) | called by muse, mutect2, varscan2
- PUS1 | c.-446G>T | 5'UTR (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2, varscan2
- QDPR | c.*435T>G | 3'UTR (SNP) | VAF 46/134 reads (34%) | called by muse, mutect2, varscan2
- RASGEF1B | c.*476T>G | 3'UTR (SNP) | VAF 54/81 reads (67%) | called by muse, mutect2, varscan2
- RBM24 | c.*596C>G | 3'UTR (SNP) | VAF 25/100 reads (25%) | called by muse, mutect2, varscan2
- RHOBTB1 | c.*268T>G | 3'UTR (SNP) | VAF 38/81 reads (47%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159801 G>A | 5'Flank (SNP) | VAF 14/26 reads (54%) | called by muse, mutect2, varscan2
- SGK1 | c.152+29C>G | Intron (SNP) | VAF 44/114 reads (39%) | catalogued as rs375352335; called by muse, mutect2, varscan2
- SIGLEC12 | c.*92T>G | 3'UTR (SNP) | VAF 27/106 reads (25%) | called by muse, mutect2, varscan2
- SLC35F1 | c.*537T>C | 3'UTR (SNP) | VAF 15/64 reads (23%) | called by muse, mutect2, varscan2
- SMAD2 | c.*4303A>T | 3'UTR (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- SOCS6 | c.*547T>A | 3'UTR (SNP) | VAF 122/173 reads (71%) | called by muse, mutect2, varscan2
- SORBS2 | c.*496T>C | 3'UTR (SNP) | VAF 35/119 reads (29%) | catalogued as COSV99510448; called by muse, mutect2, varscan2
- TFAP2D | c.-257A>G | 5'UTR (SNP) | VAF 19/63 reads (30%) | called by muse, mutect2, varscan2
- THEM4 | c.286+37A>C | Intron (SNP) | VAF 29/84 reads (35%) | called by muse, mutect2, varscan2
- VRK1 | c.*279A>C | 3'UTR (SNP) | VAF 25/57 reads (44%) | called by muse, mutect2, varscan2
- ZNF567 | chr19:36723316 ins CTAC | 3'Flank (INS) | VAF 33/137 reads (24%) | called by pindel, varscan2
- ZNF567 | chr19:36723323 ins CAG | 3'Flank (INS) | VAF 47/142 reads (33%) | called by muse*, mutect2, varscan2*
- ZNF569 | c.*328C>T | 3'UTR (SNP) | VAF 28/79 reads (35%) | catalogued as rs780242405; called by muse, mutect2, varscan2
- ZNF716 | c.*2263C>T | 3'UTR (SNP) | VAF 17/51 reads (33%) | catalogued as rs572958733; called by muse, mutect2, varscan2
